Gene-level copy-number profile of tumor specimen TCGA-66-2766-01A from TCGA case TCGA-66-2766, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.2 years (19,814 days).
Specimen TCGA-66-2766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3e4de4f4-18eb-4003-b22c-27a79ba94e55.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2766-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b418f5f3-7a45-4c18-91e2-5012a8418294

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 1,442; copy number 2: 22,782; copy number 3: 20,555; copy number 4: 9,768; copy number 5: 3,023; copy number 6: 692; copy number 7: 993; copy number 8: 146; copy number 9: 393; copy number 19: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2766-01A-01D-0844-01): tumor purity 0.75, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:34,872,641–35,872,198, 7 genes: FECHP1, KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1.
- chr16:21,587,627–21,919,156, 12 genes: AC005632.1, METTL9, AC005632.3, IGSF6, RNU6-1005P, RNU6-196P, OTOA, AC092375.2, RRN3P1, AC092375.3, NPIPB4, SMG1P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,248 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:40,097,270–66,971,462, 424 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:11,745–9,363,053, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:17,141,015–18,445,588, 13 genes, copy number 5: AC090644.1, TBC1D5, AC090960.1, AC140076.1, RNU7-10P, AC104451.1, AC104451.2, AC104297.1, PDCL3P3, AC132807.1, AC132807.2, SATB1, AC144521.1.
- chr3:90,202,316–98,222,966, 53 genes, copy number 5–8 (within-gene range 4–8): PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P, OR5H4P.
- chr3:98,238,352–98,239,281, 1 gene, copy number 8: OR5H7P.
- chr3:145,523,538–198,222,513, 933 genes, copy number 5–19 (broad region; genes not listed).
- chr4:35,487,812–35,496,003, 2 genes, copy number 5: SEC63P2, RNU6-573P.
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr6:67,456,346–68,093,001, 10 genes, copy number 5: AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1.
- chr6:124,962,545–125,302,078, 4 genes, copy number 6 (within-gene range 3–6): RNF217, TPD52L1, HDDC2, AL121938.1.
- chr8:99,003,407–108,787,594, 176 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:39,261,107–45,772,358, 86 genes, copy number 5 (broad region; genes not listed).
- chr12:4,804,499–21,419,594, 479 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:89,181,324–114,337,626, 368 genes, copy number 5 (broad region; genes not listed).
- chr18:37,960,220–40,247,367, 18 genes, copy number 5–9: AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1.
- chr19:4,502,180–5,340,803, 28 genes, copy number 5: PLIN4, PLIN5, AC011498.4, LRG1, SEMA6B, AC011498.5, TNFAIP8L1, MYDGF, AC005339.1, DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3, AC005523.1, FEM1A, AC005523.2, TICAM1, AC027319.1, PLIN3, ARRDC5, UHRF1, MIR4747, KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1.
- chr19:7,879,445–22,245,347, 785 genes, copy number 5 (broad region; genes not listed).
- chr19:23,739,195–41,207,539, 540 genes, copy number 6–9 (broad region; genes not listed).
- chr20:30,484,925–41,383,107, 313 genes, copy number 5 (broad region; genes not listed).
- chr20:41,459,354–41,461,944, 1 gene, copy number 5: AL031667.2.
- chr22:17,980,868–21,670,237, 215 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 812. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
